Gene-level copy-number profile of tumor specimen TCGA-BW-A5NP-01A from TCGA case TCGA-BW-A5NP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 26.9 years (9,809 days).
Specimen TCGA-BW-A5NP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9cc077c8-fc34-48f5-be3b-bb4a0d445ccb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BW-A5NP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate.
https://portal.gdc.cancer.gov/files/731d6bdb-2f36-41cb-bf9d-2e8edbde25dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,331; copy number 1: 11,326; copy number 2: 37,735; copy number 3: 7,591; copy number 4: 2,046; copy number 5: 141; copy number 6: 8; copy number 8: 4; copy number 9: 80.

Homozygous deletions (total copy number 0; autosomes only): 811 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr4:184,088,706–184,221,230, 1 gene (within-gene range 0–1): ENPP6.
- chr4:184,254,509–184,474,550, 7 genes (within-gene range 0–1): AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79.
- chr8:2,517,898–39,580,134, 797 genes (broad region; genes not listed).
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–1): AC092821.1, AC092821.2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 233 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:145,002,811–145,066,685, 4 genes, copy number 8: ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr20:53,397,661–53,421,656, 2 genes, copy number 5: AL354993.1, PPIAP10.
- chr20:53,936,777–54,859,812, 9 genes, copy number 5–6: BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.
- chr20:56,459,428–59,259,113, 80 genes, copy number 9 (broad region; genes not listed).
- chr20:61,953,469–64,313,132, 138 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,326. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
